Somatic mutation profile of tumor specimen ALCH-B365-TTP1-A (aliquot ALCH-B365-TTP1-A-1-0-D-A78R-36) from ALCHEMIST case ALCH-B365, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.2 years (24,912 days).
Specimen ALCH-B365-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ccd3a0ba-5b6e-4c84-a3a7-4e80d4e3ed77.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B365-NB1-A (Blood Derived Normal), aliquot ALCH-B365-NB1-A-1-0-D-A78R-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/61b483ac-d252-4c32-a616-79a423ab2149

The open-access MAF lists 301 somatic variants for this specimen: 198 protein-altering or splice-affecting, 68 silent, 35 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 164, Silent 68, Nonsense Mutation 20, Intron 12, 3'UTR 9, Frame Shift Del 8, RNA 6, 5'UTR 3, 5'Flank 3, Splice Site 3, 3'Flank 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DLD | c.199-1G>A p.X67_splice | Splice Site (SNP) | VAF 25/307 reads (8%) | catalogued as rs1554398264; ClinVar: likely pathogenic; called by muse, mutect2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 73/296 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AANAT | c.457G>T p.V153L | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.029); catalogued as rs576095033, COSV51684152, COSV99166268; called by muse, mutect2, varscan2
- AASS | c.2641G>T p.A881S | Missense Mutation (SNP) | VAF 57/411 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV100741768; called by muse, mutect2, varscan2
- ABCA8 | c.892G>T p.G298C | Missense Mutation (SNP) | VAF 12/127 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99284416; called by muse, mutect2
- ACE | c.44C>T p.P15L | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0); catalogued as rs1355518990; called by muse, mutect2
- ADAMTS20 | c.474G>T p.Q158H | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101239206; called by muse, mutect2, varscan2
- AFF2 | c.1937C>A p.P646H | Missense Mutation (SNP) | VAF 20/354 reads (6%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.797); catalogued as COSV99667215; called by muse, mutect2
- ALLC | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 15/224 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.908); catalogued as rs756768853, COSV52998569; called by muse, mutect2
- ARHGAP4 | c.1484G>A p.R495H | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs932908124, COSV63133337, COSV63134681; called by muse, mutect2
- ARHGEF4 | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 105/481 reads (22%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.062); catalogued as rs527734596; called by muse, mutect2, varscan2
- BRIP1 | c.3532G>T p.E1178* | Nonsense Mutation (SNP) | VAF 33/185 reads (18%) | catalogued as rs876661115; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C12orf75 | c.104G>A p.R35K | Missense Mutation (SNP) | VAF 34/208 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as rs1291641518; called by muse, varscan2
- CFAP47 | c.9410C>A p.P3137Q | Missense Mutation (SNP) | VAF 16/280 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs1556024855; called by muse, mutect2
- CPA6 | c.24G>T p.R8S | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.003); catalogued as COSV52735688; called by muse, mutect2, varscan2
- CRISPLD1 | c.13G>T p.A5S | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs1165616521, COSV51551479; called by muse, mutect2
- CTC1 | c.1954G>T p.V652L | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.011); catalogued as rs769147608; called by muse, mutect2, varscan2
- CTNNA1 | c.781G>T p.A261S | Missense Mutation (SNP) | VAF 47/378 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.235); catalogued as COSV57078408; called by muse, mutect2, varscan2
- CYP1A2 | c.1378G>A p.G460R | Missense Mutation (SNP) | VAF 19/234 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs768979898, COSV59660694; called by muse, mutect2
- ENO2 | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 13/194 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.703); catalogued as COSV50395354; called by muse, mutect2
- ERICH3 | c.2119G>T p.E707* | Nonsense Mutation (SNP) | VAF 37/197 reads (19%) | catalogued as COSV58610807; called by muse, mutect2, varscan2
- ERICH6B | c.913C>A p.P305T | Missense Mutation (SNP) | VAF 27/168 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as COSV53923808; called by mutect2, varscan2
- ESCO2 | c.1674-2del p.X558_splice | Splice Site (DEL) | VAF 44/319 reads (14%) | catalogued as CS083901; called by mutect2, pindel, varscan2
- FAM9A | c.199G>T p.A67S | Missense Mutation (SNP) | VAF 46/204 reads (23%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.923); catalogued as COSV101121378; called by muse, mutect2, varscan2
- GLYR1 | c.457G>T p.E153* | Nonsense Mutation (SNP) | VAF 37/228 reads (16%) | catalogued as COSV58928220; called by muse, mutect2, varscan2
- GPRASP2 | c.451G>T p.V151F | Missense Mutation (SNP) | VAF 39/175 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.209); catalogued as COSV59992768; called by muse, mutect2, varscan2
- GTF2E1 | c.1306G>C p.D436H | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.085); catalogued as COSV52206204; called by muse, mutect2
- GTF2IRD1 | c.1745G>T p.G582V | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV56092734; called by muse, mutect2, varscan2
- H1-5 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 17/219 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.93); catalogued as rs780574435, COSV58901041; called by muse, mutect2
- ICE1 | c.1788A>T p.K596N | Missense Mutation (SNP) | VAF 23/214 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.047); catalogued as COSV99665991; called by muse, mutect2, varscan2
- IGKV2D-26 | c.116C>A p.A39D | Missense Mutation (SNP) | VAF 50/377 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs1286371616; called by muse, mutect2, varscan2
- INHBA | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 89/300 reads (30%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.542); catalogued as COSV54221668; called by muse, mutect2, varscan2
- IRS4 | c.188G>T p.R63L | Missense Mutation (SNP) | VAF 20/298 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.119); catalogued as rs773020471; called by muse, mutect2
- ITGA9 | c.562G>T p.G188* | Nonsense Mutation (SNP) | VAF 64/349 reads (18%) | catalogued as COSV53245227, COSV99292874; called by muse, mutect2, varscan2
- KRTAP19-4 | c.152C>G p.P51R | Missense Mutation (SNP) | VAF 85/459 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100478407; called by muse, mutect2, varscan2
- LAMB4 | c.1274G>T p.C425F | Missense Mutation (SNP) | VAF 29/196 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52716835; called by muse, mutect2, varscan2
- LEFTY2 | c.61G>T p.A21S | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.19); catalogued as COSV64747230; called by muse, mutect2, varscan2
- LRP1B | c.9274C>A p.L3092I | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as COSV67227970; called by muse, varscan2
- LRRC7 | c.2513G>A p.R838K (on ENST00000651989 / NM_001370785.2; = p.R805K on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/207 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.236); catalogued as COSV50630191; called by muse, mutect2, varscan2
- LYPD6B | c.364C>T p.H122Y (on ENST00000409029 / NM_001317004.1; = p.H146Y on NM_177964.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.961); catalogued as rs778188401, COSV54519609; called by muse, mutect2, varscan2
- MALRD1 | c.5586del p.F1863Lfs*29 | Frame Shift Del (DEL) | VAF 53/289 reads (18%) | catalogued as COSV65978594; called by mutect2, pindel, varscan2
- MTOR | c.5347G>A p.D1783N | Missense Mutation (SNP) | VAF 14/232 reads (6%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.989); catalogued as rs1471906651, COSV63872427; called by muse, mutect2
- MYH11 | c.5122C>T p.L1708F | Missense Mutation (SNP) | VAF 43/380 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.393); catalogued as rs1353911032; called by muse, mutect2, varscan2
- NPAP1 | c.790G>T p.E264* | Nonsense Mutation (SNP) | VAF 18/123 reads (15%) | catalogued as COSV100275712; called by muse, mutect2, varscan2
- OPRD1 | c.903C>A p.H301Q | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.953); catalogued as COSV52382556; called by muse, mutect2, varscan2
- OR13G1 | c.277G>T p.G93C | Missense Mutation (SNP) | VAF 16/254 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV62943422; called by muse, mutect2
- OR1K1 | c.496C>A p.R166S | Missense Mutation (SNP) | VAF 20/284 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.597); catalogued as rs143974581; called by muse, mutect2
- OR2M5 | c.591G>T p.K197N | Missense Mutation (SNP) | VAF 46/394 reads (12%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV63547034; called by muse, mutect2, varscan2
- OR4K5 | c.796C>T p.P266S | Missense Mutation (SNP) | VAF 10/222 reads (5%) | SIFT tolerated (0.81); PolyPhen benign (0.01); catalogued as COSV60002766, COSV60004744; called by muse, mutect2
- PAK1 | c.772+1G>A p.X258_splice | Splice Site (SNP) | VAF 8/125 reads (6%) | catalogued as rs1482673833, COSV53695373, COSV53697384; called by muse, mutect2
- PAK5 | c.1918G>T p.E640* | Nonsense Mutation (SNP) | VAF 46/239 reads (19%) | catalogued as COSV62026355, COSV62029552; called by muse, mutect2, varscan2
- PBX4 | c.235G>T p.A79S | Missense Mutation (SNP) | VAF 26/177 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.698); catalogued as COSV52061690; called by muse, mutect2, varscan2
- PCDHA6 | c.1256C>A p.S419* | Nonsense Mutation (SNP) | VAF 44/512 reads (9%) | catalogued as COSV101131218; called by muse, mutect2
- PGA5 | c.745G>T p.E249* | Nonsense Mutation (SNP) | VAF 30/550 reads (5%) | catalogued as COSV56715594; called by muse, mutect2
- PIK3C2G | c.562C>A p.P188T | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.049); catalogued as COSV56830822; called by muse, mutect2, varscan2
- POLE3 | c.77G>T p.G26V | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55913235; called by muse, mutect2
- PPP1R2 | c.295A>G p.I99V | Missense Mutation (SNP) | VAF 48/240 reads (20%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs1435269209; called by muse, mutect2, varscan2
- PRKCQ | c.1847G>A p.R616Q | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs781395221, COSV54111077; called by muse, mutect2, varscan2
- PRODH2 | c.1493T>A p.L498Q (on ENST00000301175; = p.L422Q on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99995479; called by muse, mutect2
- PTGER3 | c.184G>A p.G62S | Missense Mutation (SNP) | VAF 46/288 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1309227156; called by muse, mutect2, varscan2
- PTGFR | c.238G>A p.G80S | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV66116357; called by muse, mutect2, varscan2
- REG3G | c.61C>A p.L21M | Missense Mutation (SNP) | VAF 50/303 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.173); catalogued as COSV99709189; called by muse, mutect2, varscan2
- SBK2 | c.427G>T p.G143W | Missense Mutation (SNP) | VAF 39/176 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100704973, COSV100705237; called by muse, mutect2, varscan2
- SQSTM1 | c.754G>T p.G252C | Missense Mutation (SNP) | VAF 33/246 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs765959386; called by muse, mutect2, varscan2
- TCHH | c.4649G>A p.R1550H | Missense Mutation (SNP) | VAF 24/436 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.564); catalogued as rs779215399, COSV64273878; called by muse, mutect2
- TENM1 | c.5495G>T p.W1832L | Missense Mutation (SNP) | VAF 10/165 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV64429945; called by muse, mutect2
- TFAM | c.476G>T p.R159L | Missense Mutation (SNP) | VAF 24/192 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100876100; called by muse, mutect2, varscan2
- TMEM130 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT tolerated (0.85); PolyPhen benign (0.007); catalogued as rs375013520; called by muse, mutect2, varscan2
- TP53 | c.583del p.I195Sfs*52 | Frame Shift Del (DEL) | VAF 51/238 reads (21%) | catalogued as COSV52677568, COSV52809310, COSV53233300; called by mutect2, pindel, varscan2
- TRERF1 | c.125G>T p.G42V | Missense Mutation (SNP) | VAF 46/268 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as COSV61673833; called by muse, mutect2, varscan2
- TSHZ2 | c.2918G>T p.R973L | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as CM142650, COSV61587217, COSV61587698; called by muse, mutect2, varscan2
- TTN | c.83240C>A p.T27747N (on ENST00000591111; = p.T20323N on NM_003319.4) | Missense Mutation (SNP) | VAF 94/521 reads (18%) | PolyPhen possibly damaging (0.848); catalogued as rs775200192, COSV100606960; called by muse, mutect2, varscan2
- USP29 | c.2190G>T p.M730I | Missense Mutation (SNP) | VAF 31/194 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as COSV54144863; called by muse, mutect2, varscan2
- WNT4 | c.853C>A p.R285S | Missense Mutation (SNP) | VAF 64/408 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.037); catalogued as rs530880163; called by muse, mutect2, varscan2
- ZEB1 | c.44C>A p.P15Q | Missense Mutation (SNP) | VAF 100/336 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100313417; called by muse, mutect2, varscan2
- ZFHX4 | c.5048C>A p.P1683H | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.723); catalogued as COSV51509010; called by muse, mutect2, varscan2
- ZFP57 | c.1529C>A p.T510N | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.051); catalogued as rs773321909; called by muse, mutect2, varscan2
- ZNF264 | c.1268G>C p.G423A | Missense Mutation (SNP) | VAF 69/343 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54041136; called by muse, mutect2, varscan2
- ZNF835 | c.1462G>T p.A488S | Missense Mutation (SNP) | VAF 18/268 reads (7%) | SIFT tolerated (0.94); PolyPhen benign (0.013); catalogued as COSV73379338; called by muse, mutect2
- ABCC2 | c.1186A>G p.I396V | Missense Mutation (SNP) | VAF 63/409 reads (15%) | SIFT tolerated (0.6); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AC011005.1 | c.855G>T p.R285S | Missense Mutation (SNP) | VAF 37/216 reads (17%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACACB | c.4001G>T p.R1334L | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- AGGF1 | c.1458G>T p.Q486H | Missense Mutation (SNP) | VAF 28/360 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.017); called by muse, mutect2
- AIM2 | c.779T>A p.L260H | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- AKT3 | c.286G>C p.E96Q | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- AOC1 | c.901C>A p.R301S | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.104); called by muse, mutect2
- APEX2 | c.80G>C p.C27S | Missense Mutation (SNP) | VAF 22/238 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.006); called by muse, mutect2
- ARMH4 | c.1666G>T p.V556F | Missense Mutation (SNP) | VAF 47/195 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- ASPM | c.10411G>T p.D3471Y | Missense Mutation (SNP) | VAF 38/332 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, varscan2
- ATP1A2 | c.1284_1296del p.A429Qfs*33 | Frame Shift Del (DEL) | VAF 33/233 reads (14%) | called by pindel, varscan2
- ATP7A | c.3658G>T p.D1220Y | Missense Mutation (SNP) | VAF 34/318 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- BOD1L1 | c.2528G>A p.R843K | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- BRWD3 | c.1483C>A p.L495I | Missense Mutation (SNP) | VAF 17/212 reads (8%) | SIFT tolerated (0.66); PolyPhen benign (0.05); called by muse, mutect2
- C6orf15 | c.654G>T p.W218C | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- CACNA1B | c.5517G>C p.L1839F | Missense Mutation (SNP) | VAF 15/193 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- CACNA1H | c.3495_3496del p.L1166Afs*14 | Frame Shift Del (DEL) | VAF 20/149 reads (13%) | called by mutect2, pindel, varscan2
- CACNA2D1 | c.2982A>T p.L994F (on ENST00000356253 / NM_001366867.1; = p.L982F on NM_000722.4) | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.193); called by muse, mutect2
- CARD11 | c.1624C>A p.L542M | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- CC2D1A | c.2513G>A p.G838E | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- CD22 | c.387G>T p.M129I | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- CD276 | c.1246G>T p.E416* (on ENST00000318443 / NM_001024736.2; = p.E198* on NM_025240.2 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 43/547 reads (8%) | called by muse, mutect2
- CDH9 | c.1771T>G p.C591G | Missense Mutation (SNP) | VAF 100/633 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CFAP46 | c.645G>C p.Q215H | Missense Mutation (SNP) | VAF 28/243 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- CFAP61 | c.2204C>T p.S735F | Missense Mutation (SNP) | VAF 22/228 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CKAP5 | c.3391G>T p.G1131* | Nonsense Mutation (SNP) | VAF 24/290 reads (8%) | called by muse, mutect2
- CMTR2 | c.2229T>A p.N743K | Missense Mutation (SNP) | VAF 29/152 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- COL11A1 | c.820G>T p.G274W | Missense Mutation (SNP) | VAF 54/305 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CYLC1 | c.499C>A p.H167N | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- DLG4 | c.923C>T p.P308L (on ENST00000399506 / NM_001321075.3; = p.P351L on NM_001365.4) | Missense Mutation (SNP) | VAF 37/176 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- DLX2 | c.803G>T p.S268I | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNAH8 | c.3401T>C p.I1134T | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.38); called by muse, mutect2
- DSG1 | c.2141C>T p.S714F | Missense Mutation (SNP) | VAF 31/215 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- EDC4 | c.3186G>T p.M1062I | Missense Mutation (SNP) | VAF 44/173 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- ELF3 | c.920G>C p.R307P | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ELFN1 | c.1397T>C p.I466T | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.017); called by mutect2, varscan2
- ELOVL4 | c.670A>T p.I224F | Missense Mutation (SNP) | VAF 24/296 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); called by muse, mutect2
- ERBB4 | c.3220G>T p.E1074* | Nonsense Mutation (SNP) | VAF 59/273 reads (22%) | called by muse, mutect2, varscan2
- FAM135B | c.2647C>G p.P883A | Missense Mutation (SNP) | VAF 48/198 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- FAM155B | c.481A>T p.T161S | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.042); called by muse, mutect2
- FAM83B | c.2130G>C p.M710I | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.023); called by muse, mutect2
- FOXO4 | c.970C>A p.L324I | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0.258); called by muse, mutect2
- FRRS1L | c.571A>G p.R191G | Missense Mutation (SNP) | VAF 17/289 reads (6%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.994); called by muse, mutect2
- FSIP2 | c.16098T>A p.H5366Q | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2
- GABRQ | c.1741A>C p.S581R | Missense Mutation (SNP) | VAF 39/329 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.51); called by muse, mutect2, varscan2
- GFRAL | c.125G>A p.W42* | Nonsense Mutation (SNP) | VAF 50/286 reads (17%) | called by muse, mutect2, varscan2
- GTF2IRD1 | c.1744G>T p.G582C | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GUSB | c.120G>T p.E40D | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- HSFX1 | c.79G>T p.V27L | Missense Mutation (SNP) | VAF 47/281 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HSPA12A | c.694C>A p.Q232K | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.062); called by muse, mutect2
- ICAM5 | c.1337C>T p.S446F | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- IGFBP1 | c.724T>G p.S242A | Missense Mutation (SNP) | VAF 41/260 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- IGSF9 | c.1638G>A p.L546= (on ENST00000368094 / NM_001135050.2; = p.L530= on NM_020789.4) | Splice Region (SNP) | VAF 7/47 reads (15%) | called by muse, mutect2, varscan2
- ITGAL | c.2300T>A p.F767Y | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNA5 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 13/204 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2
- KCNH8 | c.872C>G p.A291G | Missense Mutation (SNP) | VAF 19/170 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- KCNJ15 | c.933T>A p.F311L | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KCNK1 | c.650_658del p.Y217_C219del | In Frame Del (DEL) | VAF 34/312 reads (11%) | called by mutect2, pindel
- KLK1 | c.86_87delinsT p.W29Lfs*75 | Frame Shift Del (DEL) | VAF 9/73 reads (12%) | called by pindel, varscan2*
- KRTAP22-1 | c.6C>G p.S2R | Missense Mutation (SNP) | VAF 57/553 reads (10%) | PolyPhen benign (0.305); called by muse, mutect2, varscan2
- KRTAP3-3 | c.275C>A p.P92H | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- LILRB2 | c.1715G>T p.R572L | Missense Mutation (SNP) | VAF 59/304 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- LMO1 | c.122A>G p.D41G | Missense Mutation (SNP) | VAF 12/346 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.34); called by muse, mutect2
- LRRIQ1 | c.3274T>A p.C1092S | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- MACF1 | c.15415C>T p.Q5139* (on ENST00000372915; = p.Q3072* on NM_012090.5) | Nonsense Mutation (SNP) | VAF 9/96 reads (9%) | called by muse, mutect2
- MEGF9 | c.1470G>T p.Q490H | Missense Mutation (SNP) | VAF 47/380 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- MICAL2 | c.2134C>G p.Q712E | Missense Mutation (SNP) | VAF 19/192 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- MKLN1 | c.1148G>T p.G383V | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MROH2B | c.2515C>T p.L839F | Missense Mutation (SNP) | VAF 32/229 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYH4 | c.2340G>A p.M780I | Missense Mutation (SNP) | VAF 27/160 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- MYRFL | c.913A>G p.T305A | Missense Mutation (SNP) | VAF 29/169 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- MZT2A | c.467G>A p.G156D | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- NARF | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NIBAN2 | c.896C>G p.P299R | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.972); called by muse, mutect2
- NPAS2 | c.2101C>G p.R701G | Missense Mutation (SNP) | VAF 35/300 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.03); called by muse, varscan2
- NPAS4 | c.1127C>A p.P376H | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- NUTM2G | c.2021C>A p.S674* | Nonsense Mutation (SNP) | VAF 46/247 reads (19%) | called by mutect2, varscan2
- OBSCN | c.3259G>T p.E1087* | Nonsense Mutation (SNP) | VAF 32/255 reads (13%) | called by muse, mutect2, varscan2
- OR10V1 | c.789del p.S264Vfs*23 | Frame Shift Del (DEL) | VAF 44/259 reads (17%) | called by mutect2, pindel, varscan2
- OR2T35 | c.860C>A p.P287Q | Missense Mutation (SNP) | VAF 22/482 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- OR4A5 | c.613A>G p.M205V | Missense Mutation (SNP) | VAF 13/137 reads (9%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0.006); called by muse, mutect2
- OR9Q2 | c.437C>A p.T146N | Missense Mutation (SNP) | VAF 20/244 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.425); called by muse, mutect2
- PABPC4L | c.456G>T p.R152S | Missense Mutation (SNP) | VAF 48/296 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- PARG | c.318A>G p.I106M | Missense Mutation (SNP) | VAF 20/172 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.027); called by muse, mutect2
- PCOLCE | c.141C>A p.Y47* | Nonsense Mutation (SNP) | VAF 9/58 reads (16%) | called by muse, mutect2, varscan2
- PDE6B | c.1888C>A p.L630M | Missense Mutation (SNP) | VAF 27/197 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- PDE8B | c.669G>T p.E223D | Missense Mutation (SNP) | VAF 58/554 reads (10%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- PDHA2 | c.701C>G p.A234G | Missense Mutation (SNP) | VAF 25/221 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.699); called by muse, mutect2, varscan2
- PKHD1L1 | c.11246C>T p.T3749I | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.045); called by muse, mutect2
- PLCE1 | c.1275G>T p.K425N | Missense Mutation (SNP) | VAF 22/208 reads (11%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2
- PRKCA | c.1806G>T p.W602C | Missense Mutation (SNP) | VAF 33/197 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PTGER3 | c.185G>T p.G62V | Missense Mutation (SNP) | VAF 46/290 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPRN | c.2827G>A p.E943K | Missense Mutation (SNP) | VAF 27/166 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- RABGGTA | c.1499C>T p.S500F | Missense Mutation (SNP) | VAF 38/156 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- RUNX1T1 | c.814C>A p.P272T (on ENST00000265814 / NM_001198628.1; = p.P245T on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/545 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); called by muse, mutect2
- RXFP2 | c.1969G>A p.V657I | Missense Mutation (SNP) | VAF 28/298 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2
- RYR3 | c.4622G>A p.R1541K | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.61); called by muse, mutect2
- SCN5A | c.943C>A p.L315M | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SEMA6D | c.2231G>C p.S744T (on ENST00000316364 / NM_153618.2; = p.S682T on NM_020858.2) | Missense Mutation (SNP) | VAF 48/235 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SERPINB4 | c.195C>A p.N65K | Missense Mutation (SNP) | VAF 45/254 reads (18%) | SIFT tolerated (0.74); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SIGLEC8 | c.320G>T p.C107F | Missense Mutation (SNP) | VAF 28/454 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TBX4 | c.401G>T p.W134L | Missense Mutation (SNP) | VAF 72/432 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TEX44 | c.177del p.R60Gfs*42 | Frame Shift Del (DEL) | VAF 58/431 reads (13%) | called by mutect2, pindel, varscan2
- TMEM132C | c.457A>T p.I153F | Missense Mutation (SNP) | VAF 77/390 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- TMEM255B | c.655del p.A219Pfs*37 | Frame Shift Del (DEL) | VAF 15/86 reads (17%) | called by mutect2, pindel, varscan2
- TNFSF18 | c.421A>T p.K141* | Nonsense Mutation (SNP) | VAF 17/144 reads (12%) | called by muse, mutect2, varscan2
- TRAV34 | c.146T>A p.L49* | Nonsense Mutation (SNP) | VAF 35/155 reads (23%) | called by muse, mutect2, varscan2
- TRO | c.4199C>A p.P1400Q | Missense Mutation (SNP) | VAF 19/170 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- VSIG10L | c.1873G>T p.G625W | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- VWA3A | c.1993C>A p.H665N | Missense Mutation (SNP) | VAF 61/324 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- WDR13 | c.1226G>T p.R409L | Missense Mutation (SNP) | VAF 11/252 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.41); called by muse, mutect2
- ZC3H13 | c.2539G>T p.D847Y | Missense Mutation (SNP) | VAF 10/159 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); called by muse, mutect2
- ZC3HAV1 | c.1203G>T p.K401N | Missense Mutation (SNP) | VAF 36/432 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.046); called by muse, mutect2
- ZNF555 | c.318A>T p.R106S | Missense Mutation (SNP) | VAF 45/228 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZNF592 | c.3049C>T p.Q1017* | Nonsense Mutation (SNP) | VAF 94/512 reads (18%) | called by muse, mutect2, varscan2
- ZNF618 | c.1864A>T p.S622C (on ENST00000374126 / NM_001318042.2; = p.S529C on NM_133374.2) | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- ZNF721 | c.1874G>T p.G625V (on ENST00000338977; = p.G637V on NM_133474.4) | Missense Mutation (SNP) | VAF 33/320 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF75D | c.895G>T p.G299* | Nonsense Mutation (SNP) | VAF 20/196 reads (10%) | called by muse, mutect2, varscan2
- ZNF831 | c.4814G>C p.C1605S | Missense Mutation (SNP) | VAF 52/193 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ACSM4 | c.1104G>A p.E368= | Silent (SNP) | VAF 40/189 reads (21%) | catalogued as COSV101257076; called by muse, mutect2, varscan2
- ADAMTS2 | c.360G>T p.L120= | Silent (SNP) | VAF 21/176 reads (12%) | catalogued as rs1394532631; called by muse, mutect2, varscan2
- AGO3 | c.1521G>A p.R507= | Silent (SNP) | VAF 20/216 reads (9%) | catalogued as rs1399614341; called by muse, mutect2
- AGPAT1 | c.142C>T p.L48= | Silent (SNP) | VAF 28/480 reads (6%) | called by muse, mutect2
- AMER3 | c.42G>T p.L14= | Silent (SNP) | VAF 39/227 reads (17%) | catalogued as rs753033858; called by muse, mutect2, varscan2
- AMFR | c.1302G>T p.P434= | Silent (SNP) | VAF 28/308 reads (9%) | catalogued as COSV99316181; called by muse, mutect2
- API5 | c.687C>G p.P229= | Silent (SNP) | VAF 55/362 reads (15%) | called by muse, mutect2, varscan2
- BAHCC1 | c.5248C>T p.L1750= | Silent (SNP) | VAF 6/134 reads (4%) | called by muse, mutect2
- BMP7 | c.912C>G p.S304= | Silent (SNP) | VAF 77/326 reads (24%) | called by muse, mutect2, varscan2
- BRPF1 | c.2751C>T p.S917= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as rs1162241224; called by muse, mutect2, varscan2
- BTNL3 | c.924T>A p.T308= | Silent (SNP) | VAF 21/174 reads (12%) | called by muse, mutect2, varscan2
- C4B | c.2556G>A p.R852= | Silent (SNP) | VAF 28/678 reads (4%) | catalogued as rs776146177; called by muse, mutect2
- CACNG2 | c.330G>A p.L110= | Silent (SNP) | VAF 57/290 reads (20%) | catalogued as rs760853526, COSV100268739; called by muse, mutect2, varscan2
- CAMTA2 | c.708G>A p.G236= | Silent (SNP) | VAF 15/194 reads (8%) | called by muse, mutect2
- CCDC106 | c.78A>T p.A26= | Silent (SNP) | VAF 20/286 reads (7%) | catalogued as COSV99553186; called by muse, mutect2
- CCR1 | c.57G>T p.G19= | Silent (SNP) | VAF 8/45 reads (18%) | called by muse, mutect2
- CIB3 | c.213C>A p.R71= | Silent (SNP) | VAF 18/114 reads (16%) | called by muse, mutect2, varscan2
- COL4A6 | c.4788C>T p.S1596= | Silent (SNP) | VAF 23/291 reads (8%) | catalogued as rs1332804922; called by muse, mutect2
- COL6A3 | c.6318A>G p.V2106= | Silent (SNP) | VAF 81/548 reads (15%) | called by muse, mutect2, varscan2
- COL6A3 | c.1797C>T p.S599= | Silent (SNP) | VAF 44/332 reads (13%) | called by muse, mutect2, varscan2
- CPS1 | c.3243G>T p.L1081= | Silent (SNP) | VAF 52/329 reads (16%) | catalogued as COSV51811179; called by muse, mutect2, varscan2
- DHX57 | c.1947G>T p.L649= | Silent (SNP) | VAF 50/317 reads (16%) | called by muse, mutect2, varscan2
- DOT1L | c.507C>T p.V169= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as rs760870688; called by muse, mutect2, varscan2
- DSCAM | c.1401C>T p.S467= | Silent (SNP) | VAF 89/639 reads (14%) | called by muse, mutect2, varscan2
- EIF4G1 | c.1623A>T p.V541= (on ENST00000346169 / NM_198241.3; = p.V345= on NM_004953.5) | Silent (SNP) | VAF 61/347 reads (18%) | called by muse, mutect2, varscan2
- FAM25G | c.63C>A p.T21= | Silent (SNP) | VAF 23/168 reads (14%) | called by muse, mutect2, varscan2
- FAT3 | c.9621C>A p.A3207= | Silent (SNP) | VAF 32/352 reads (9%) | called by muse, mutect2
- FBN2 | c.2634G>A p.S878= | Silent (SNP) | VAF 18/213 reads (8%) | catalogued as rs143905167; ClinVar: likely benign; called by muse, mutect2
- FBP1 | c.339A>G p.K113= | Silent (SNP) | VAF 14/278 reads (5%) | called by muse, mutect2
- FGF3 | c.315C>G p.L105= | Silent (SNP) | VAF 65/306 reads (21%) | called by muse, mutect2, varscan2
- FREM3 | c.6228C>A p.G2076= | Silent (SNP) | VAF 42/203 reads (21%) | catalogued as rs1351213552; called by muse, mutect2, varscan2
- FRYL | c.7293A>G p.L2431= | Silent (SNP) | VAF 6/66 reads (9%) | called by muse, mutect2
- HTR3A | c.1389C>A p.A463= | Silent (SNP) | VAF 26/350 reads (7%) | catalogued as COSV55468543; called by muse, mutect2
- IGFBPL1 | c.774G>T p.V258= | Silent (SNP) | VAF 46/272 reads (17%) | called by muse, mutect2, varscan2
- IZUMO3 | c.625C>A p.R209= (on ENST00000543880 / NM_001365008.2; = p.R203= on NM_001271706.1) | Silent (SNP) | VAF 7/127 reads (6%) | catalogued as COSV69048155; called by muse, mutect2
- KCNT2 | c.3240C>A p.L1080= | Silent (SNP) | VAF 18/175 reads (10%) | called by muse, varscan2
- LRRTM1 | c.114G>T p.G38= | Silent (SNP) | VAF 11/66 reads (17%) | called by muse, mutect2, varscan2
- MFN1 | c.1575C>A p.S525= | Silent (SNP) | VAF 10/233 reads (4%) | called by muse, mutect2
- NCAM2 | c.603C>T p.I201= | Silent (SNP) | VAF 10/117 reads (9%) | called by muse, mutect2
- NHSL2 | c.1359C>A p.I453= (on ENST00000510661; = p.I819= on NM_001013627.2) | Silent (SNP) | VAF 18/268 reads (7%) | called by muse, mutect2
- NTM | c.603C>T p.C201= | Silent (SNP) | VAF 27/365 reads (7%) | called by muse, mutect2
- OPN4 | c.1098C>A p.P366= | Silent (SNP) | VAF 12/89 reads (13%) | called by muse, mutect2, varscan2
- OPRD1 | c.904C>T p.L302= | Silent (SNP) | VAF 9/43 reads (21%) | called by muse, mutect2, varscan2
- OR5V1 | c.765C>A p.A255= | Silent (SNP) | VAF 11/81 reads (14%) | called by muse, mutect2, varscan2
- OR6B2 | c.54C>G p.P18= | Silent (SNP) | VAF 28/126 reads (22%) | called by muse, mutect2
- OTOF | c.780G>T p.V260= | Silent (SNP) | VAF 33/195 reads (17%) | called by muse, mutect2, varscan2
- PCDHB13 | c.543C>A p.V181= | Silent (SNP) | VAF 43/406 reads (11%) | called by muse, mutect2, varscan2
- PEX5L | c.12A>T p.G4= | Silent (SNP) | VAF 10/108 reads (9%) | called by muse, mutect2, varscan2
- PHLDB2 | c.198G>A p.V66= | Silent (SNP) | VAF 20/165 reads (12%) | catalogued as rs1339497407; called by muse, mutect2, varscan2
- PKD1 | c.1674G>A p.T558= | Silent (SNP) | VAF 14/186 reads (8%) | catalogued as rs757658330; ClinVar: benign; called by muse, mutect2
- PTPRC | c.2017C>A p.R673= | Silent (SNP) | VAF 32/233 reads (14%) | called by muse, mutect2, varscan2
- RAPGEF2 | c.411C>A p.A137= | Silent (SNP) | VAF 38/198 reads (19%) | called by muse, mutect2, varscan2
- RCBTB2 | c.303C>G p.A101= | Silent (SNP) | VAF 22/228 reads (10%) | called by muse, mutect2
- RRAGB | c.219C>A p.G73= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV53331622; called by muse, mutect2
- RXFP3 | c.1218C>A p.R406= | Silent (SNP) | VAF 38/201 reads (19%) | called by muse, mutect2, varscan2
- SHPRH | c.2148A>G p.R716= | Silent (SNP) | VAF 8/114 reads (7%) | called by muse, mutect2
- SLC10A4 | c.615G>A p.T205= | Silent (SNP) | VAF 15/106 reads (14%) | catalogued as rs766625933; called by muse, varscan2
- SRCAP | c.7812T>A p.P2604= | Silent (SNP) | VAF 46/269 reads (17%) | called by muse, mutect2, varscan2
- TENM4 | c.6552A>G p.G2184= | Silent (SNP) | VAF 56/241 reads (23%) | catalogued as rs766145028, COSV53604536; called by muse, mutect2, varscan2
- TMED7 | c.75G>T p.L25= | Silent (SNP) | VAF 27/174 reads (16%) | called by muse, mutect2, varscan2
- TRIM33 | c.2907T>A p.L969= | Silent (SNP) | VAF 15/170 reads (9%) | called by muse, mutect2
- TRPM2 | c.2697C>T p.L899= | Silent (SNP) | VAF 15/103 reads (15%) | catalogued as rs1275980958; called by muse, mutect2, varscan2
- VPS4B | c.645G>T p.L215= | Silent (SNP) | VAF 13/148 reads (9%) | called by muse, mutect2
- ZMPSTE24 | c.381G>T p.L127= | Silent (SNP) | VAF 44/346 reads (13%) | called by muse, mutect2, varscan2
- ZNF208 | c.327C>T p.A109= | Silent (SNP) | VAF 6/44 reads (14%) | called by muse, mutect2, varscan2
- ZNF407 | c.5343G>T p.G1781= | Silent (SNP) | VAF 12/101 reads (12%) | catalogued as rs766600453; called by muse, mutect2, varscan2
- ZNF462 | c.4749G>A p.P1583= | Silent (SNP) | VAF 30/154 reads (19%) | catalogued as rs756538263; called by muse, mutect2, varscan2
- ZNF567 | c.1431T>C p.Y477= (on ENST00000536254 / NM_001322913.1; = p.Y446= on NM_152603.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 29/162 reads (18%) | catalogued as rs1446677640; called by muse, mutect2, varscan2
- AAK1 | c.*9956G>T | 3'UTR (SNP) | VAF 24/165 reads (15%) | catalogued as rs760102968; called by muse, mutect2, varscan2
- AC093642.3 | n.2984C>A | RNA (SNP) | VAF 84/602 reads (14%) | called by muse, varscan2
- AP000769.5 | chr11:65500174 G>A | 5'Flank (SNP) | VAF 12/156 reads (8%) | called by muse, mutect2
- ATG7 | c.2079+50246G>T | Intron (SNP) | VAF 21/139 reads (15%) | called by muse, mutect2, varscan2
- BCAS1 | c.927+2450C>T | Intron (SNP) | VAF 55/339 reads (16%) | called by muse, mutect2, varscan2
- CTSLP8 | n.963C>A | RNA (SNP) | VAF 9/175 reads (5%) | called by muse, mutect2
- DGKZ | c.2907-29C>A | Intron (SNP) | VAF 23/203 reads (11%) | catalogued as rs1007515901; called by muse, mutect2, varscan2
- DLG2 | c.1978+3496C>T | Intron (SNP) | VAF 13/89 reads (15%) | called by muse, mutect2, varscan2
- EMX2 | c.*13A>T | 3'UTR (SNP) | VAF 33/301 reads (11%) | called by muse, mutect2
- FAM95C | c.559-71G>T | Intron (SNP) | VAF 32/288 reads (11%) | catalogued as rs1359233530; called by muse, mutect2, varscan2
- FBH1 | c.1+4834C>T | Intron (SNP) | VAF 14/130 reads (11%) | catalogued as rs770334474, COSV62983769; called by muse, mutect2
- FOLH1B | n.2056G>A | RNA (SNP) | VAF 22/248 reads (9%) | catalogued as rs1159786018; called by muse, mutect2
- GPATCH8 | c.*2025G>T | 3'UTR (SNP) | VAF 38/194 reads (20%) | called by muse, mutect2, varscan2
- IDS | c.418+41G>A | Intron (SNP) | VAF 25/323 reads (8%) | called by muse, mutect2
- MTO1 | c.1712+3988A>T | Intron (SNP) | VAF 11/104 reads (11%) | called by muse, mutect2, varscan2
- MUC19 | c.163-13C>A | Intron (SNP) | VAF 53/242 reads (22%) | catalogued as COSV101373758, COSV70102928; called by muse, mutect2, varscan2
- MYPN | c.*332G>T | 3'UTR (SNP) | VAF 15/137 reads (11%) | called by muse, mutect2, varscan2
- NELL1 | c.1549+54852T>A | Intron (SNP) | VAF 29/273 reads (11%) | called by muse, mutect2, varscan2
- NUTM1 | c.*52C>A | 3'UTR (SNP) | VAF 26/104 reads (25%) | called by muse, mutect2, varscan2
- OR2M1P | n.689C>A | RNA (SNP) | VAF 60/619 reads (10%) | called by muse, varscan2
- OR4F13P | n.1282G>A | RNA (SNP) | VAF 9/75 reads (12%) | catalogued as rs914700990; called by muse, mutect2, varscan2
- PPY | chr17:43938655 C>G | 3'Flank (SNP) | VAF 20/94 reads (21%) | called by muse, mutect2, varscan2
- PRR12 | chr19:49591676 G>T | 5'Flank (SNP) | VAF 5/32 reads (16%) | called by muse, mutect2, varscan2
- RN7SL495P | chr15:22608119 C>T | 3'Flank (SNP) | VAF 28/436 reads (6%) | catalogued as rs767535394; called by muse, mutect2
- SCX | c.*31G>A | 3'UTR (SNP) | VAF 25/116 reads (22%) | catalogued as COSV60992937; called by muse, mutect2, varscan2
- SLC6A10P | n.3562T>A | RNA (SNP) | VAF 6/24 reads (25%) | called by mutect2, varscan2
- SPAG6 | c.-94G>T | 5'UTR (SNP) | VAF 9/56 reads (16%) | called by muse, mutect2, varscan2
- ST3GAL5 | c.-17G>T | 5'UTR (SNP) | VAF 12/57 reads (21%) | called by muse, mutect2, varscan2
- TMEM135 | c.*6172G>T | 3'UTR (SNP) | VAF 12/126 reads (10%) | called by muse, mutect2
- TOPAZ1 | c.-55G>A | 5'UTR (SNP) | VAF 10/71 reads (14%) | called by muse, mutect2, varscan2
- TPI1 | c.*335G>A | 3'UTR (SNP) | VAF 16/166 reads (10%) | catalogued as rs782521774, COSV99222895; called by muse, mutect2
- TTC31 | c.*43C>T | 3'UTR (SNP) | VAF 12/64 reads (19%) | called by muse, mutect2, varscan2
- TTN | c.10360+1352C>A | Intron (SNP) | VAF 12/64 reads (19%) | called by muse, mutect2, varscan2
- UBE2A | c.44+35G>T | Intron (SNP) | VAF 6/48 reads (13%) | catalogued as COSV60636060; called by muse, mutect2, varscan2
- ZEB2 | chr2:144520305 G>C | 5'Flank (SNP) | VAF 18/130 reads (14%) | called by muse, mutect2, varscan2
